Somatic mutation profile of tumor specimen TCGA-A3-3362-01A (aliquot TCGA-A3-3362-01A-02D-1386-10) from TCGA case TCGA-A3-3362, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 60.2 years (21,988 days).
Specimen TCGA-A3-3362-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27dd3dd9-351b-4841-8e99-ef1258efc8d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3362-11A (Solid Tissue Normal), aliquot TCGA-A3-3362-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3301c15-13d3-4fe2-9eeb-23cc0d115a17

The open-access MAF lists 50 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 6, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+1G>C p.X155_splice | Splice Site (SNP) | VAF 68/191 reads (36%) | hotspot (GDC flag); catalogued as rs869025657, CS004297, CS111451, CS961708, COSV56543633, COSV56544194, COSV56546569, COSV56552736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.706T>C p.F236L | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57781014; called by muse, mutect2, varscan2
- AKAP13 | c.7525A>T p.N2509Y (on ENST00000394518 / NM_007200.5; = p.N2513Y on NM_006738.6) | Missense Mutation (SNP) | VAF 63/728 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63471763; called by muse, mutect2
- C17orf80 | c.869T>G p.I290S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV52149125; called by muse, mutect2, varscan2
- CAPRIN2 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV51836214; called by muse, mutect2, varscan2
- COL4A6 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV57881083; called by muse, mutect2, varscan2
- CYP2J2 | c.1496T>A p.V499D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV64607387; called by muse, mutect2, varscan2
- DDX50 | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV65293520; called by muse, mutect2, varscan2
- DOCK2 | c.1483-1G>A p.X495_splice | Splice Site (SNP) | VAF 12/249 reads (5%) | catalogued as COSV56993454, COSV99909547; called by muse, mutect2
- FAM184A | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58859437; called by muse, mutect2
- FAM47B | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754680296, COSV61452455, COSV61454407; called by mutect2, varscan2
- GTF2A2 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51115242; called by muse, mutect2
- HROB | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.439); catalogued as rs1158907075, COSV55371197; called by muse, mutect2, varscan2
- HSPA4L | c.1349A>T p.H450L | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV56549181; called by muse, mutect2, varscan2
- LAMB2 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59738629; called by muse, varscan2
- LUZP1 | c.3200G>T p.R1067L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV100035575, COSV56498573; called by mutect2, varscan2
- MCC | c.347A>C p.E116A | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV56737751; called by muse, mutect2, varscan2
- NHEJ1 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100592067, COSV59433595; called by muse, mutect2, varscan2
- NKX2-3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777337154, COSV60728439, COSV60728653; called by muse, mutect2
- OR10A7 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 35/394 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV58279705; called by muse, mutect2
- OR10H4 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59063307; called by muse, mutect2, varscan2
- PBRM1 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56309085; called by muse, mutect2, varscan2
- POT1 | c.983G>T p.R328I | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62935507; called by muse, mutect2, varscan2
- SKIV2L | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs1462061473, COSV64814752; called by muse, mutect2, varscan2
- SLC5A8 | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV73311296; called by muse, mutect2, varscan2
- SPHKAP | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60874257, COSV60882644; called by muse, mutect2, varscan2
- SZT2 | c.5012C>T p.P1671L (on ENST00000634258 / NM_001365999.1; = p.P1614L on NM_015284.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as COSV65175689; called by muse, mutect2, varscan2
- TAF5L | c.440A>C p.Q147P | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV51095562; called by muse, mutect2
- TTN | c.49516T>C p.Y16506H (on ENST00000591111; = p.Y9082H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | PolyPhen probably damaging (0.974); catalogued as COSV60403729; called by muse, mutect2, varscan2
- UHRF2 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs985374811, COSV52796832; called by muse, mutect2, varscan2
- YTHDC2 | c.2324A>T p.E775V | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV50756930; called by muse, mutect2, varscan2
- ZNF483 | c.499T>A p.C167S | Missense Mutation (SNP) | VAF 33/452 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58517486; called by muse, mutect2
- ZNF91 | c.2242G>T p.G748C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56094807; called by muse, mutect2, varscan2
- CNTNAP3 | c.2500del p.L834Wfs*17 | Frame Shift Del (DEL) | VAF 21/95 reads (22%) | called by mutect2, varscan2
- CPAMD8 | c.4436del p.L1479Cfs*48 (on ENST00000651564; = p.L1432Cfs*48 on NM_015692.5) | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- EFNA1 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NUP210L | c.2932_2947del p.L978Yfs*8 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by pindel, varscan2
- POTEE | c.707del p.D236Vfs*18 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | called by mutect2, varscan2
- SCN9A | c.5686del p.I1896Ffs*10 (on ENST00000303354; = p.I1885Ffs*10 on NM_002977.3) | Frame Shift Del (DEL) | VAF 26/139 reads (19%) | called by mutect2, pindel, varscan2
- ZNF483 | c.1815del p.K605Nfs*10 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- CTDSPL2 | c.204T>G p.P68= | Silent (SNP) | VAF 29/294 reads (10%) | catalogued as COSV52949066; called by muse, mutect2
- FAM221A | c.288C>T p.P96= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV61388747; called by muse, mutect2, varscan2
- FZD4 | c.1236C>G p.A412= | Silent (SNP) | VAF 68/234 reads (29%) | catalogued as COSV72294781; called by muse, mutect2
- IGSF10 | c.5796T>G p.L1932= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as COSV56793159; called by muse, mutect2, varscan2
- ILF2 | c.504T>C p.S168= | Silent (SNP) | VAF 84/357 reads (24%) | catalogued as COSV62628310; called by muse, mutect2, varscan2
- MCM3 | c.2451C>T p.L817= (on ENST00000229854 / NM_001366374.2; = p.L807= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1479242790, COSV57719784; called by muse, mutect2, varscan2
- NUP210L | c.2925A>T p.T975= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV55159603; called by muse, varscan2
- PAIP1 | c.423T>A p.S141= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV59088136; called by muse, mutect2, varscan2
- R3HDM2 | c.2859G>C p.V953= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV60416534; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129660G>T | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as COSV56756360; called by muse, varscan2
